Somatic mutation profile of tumor specimen TCGA-EP-A12J-01A (aliquot TCGA-EP-A12J-01A-11D-A12Z-10) from TCGA case TCGA-EP-A12J, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 63.0 years (22,997 days).
Specimen TCGA-EP-A12J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad388841-d008-4f31-ba56-d41e5053fe3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A12J-10A (Blood Derived Normal), aliquot TCGA-EP-A12J-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d6957b-41f6-44af-bbaf-b16c78427544

The open-access MAF lists 62 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 33, Silent 18, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 86/198 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2
- CCDC57 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as COSV58937474; called by muse, mutect2, varscan2
- CDHR1 | c.441C>T p.D147= | Splice Region (SNP) | VAF 58/110 reads (53%) | catalogued as COSV60566647; called by muse, mutect2, varscan2
- CHL1 | c.3291A>T p.L1097F (on ENST00000397491 / NM_001253387.1; = p.L1113F on NM_006614.4) | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56607355; called by muse, mutect2, varscan2
- CLEC4F | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs575554427, COSV55481757; called by muse, mutect2, varscan2
- CUTC | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs753780691, COSV65081907, COSV65082001; called by muse, varscan2
- DHX37 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58139607; called by muse, mutect2, varscan2
- DLG4 | c.1304C>T p.A435V (on ENST00000399506 / NM_001321075.3; = p.A478V on NM_001365.4) | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57242368; called by muse, mutect2, varscan2
- DST | c.7964G>T p.C2655F | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV55041645; called by muse, mutect2, varscan2
- EFEMP2 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57260851, COSV57261611; called by muse, mutect2, varscan2
- EXD3 | c.2569G>T p.E857* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV59813950; called by muse, mutect2, varscan2
- FCGR3B | c.453T>G p.F151L | Missense Mutation (SNP) | VAF 152/190 reads (80%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.822); catalogued as rs1403308226, COSV54212065; called by muse, mutect2, varscan2
- FDXR | c.1371C>G p.D457E (on ENST00000293195 / NM_024417.5; = p.D463E on NM_004110.6) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs538544564, COSV99500472; called by muse, mutect2, varscan2
- GARRE1 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55104477; called by muse, mutect2
- GPR137B | c.997T>A p.F333I | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV63993676; called by muse, mutect2, varscan2
- HNRNPL | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV55495604; called by muse, mutect2, varscan2
- HYAL4 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1481630944, COSV56138870, COSV56140506; called by muse, mutect2, varscan2
- ITPR3 | c.6790C>A p.L2264I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV65415201; called by muse, mutect2, varscan2
- KIF19 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759216207, COSV63430701; called by muse, varscan2
- LCP2 | c.986T>C p.L329S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV50468205; called by muse, mutect2, varscan2
- OR2L13 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as COSV63548953, COSV63549512; called by muse, mutect2, varscan2
- OSCAR | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 49/110 reads (45%) | catalogued as COSV52928936; called by muse, mutect2, varscan2
- PCNT | c.1499A>G p.D500G | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV64033357; called by muse, mutect2, varscan2
- PHTF2 | c.1601C>A p.S534* (on ENST00000248550 / NM_001366089.1; = p.S496* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 175/473 reads (37%) | catalogued as COSV50342047; called by muse, mutect2, varscan2
- PNMA3 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 97/110 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100937576, COSV64723053; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1524T>G p.N508K | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100544197, COSV57969449; called by mutect2, varscan2
- RFC1 | c.1842G>T p.W614C | Missense Mutation (SNP) | VAF 238/539 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62901244; called by muse, mutect2, varscan2
- SIMC1 | c.2475C>A p.F825L (on ENST00000443967 / NM_001308196.1; = p.F410L on NM_198567.5) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100055208; called by muse, mutect2, varscan2
- SIMC1 | c.2476C>A p.R826S (on ENST00000443967 / NM_001308196.1; = p.R411S on NM_198567.5) | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.906); catalogued as COSV100055210, COSV53799180; called by muse, mutect2, varscan2
- SLC25A12 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 189/456 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV55537566; called by muse, mutect2, varscan2
- SLC4A10 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1261502891, COSV55788035; called by muse, mutect2, varscan2
- SYCP1 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV65701088; called by muse, mutect2, varscan2
- SYNDIG1L | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV59048599; called by muse, mutect2, varscan2
- TMTC2 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 183/473 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV58284894; called by muse, mutect2, varscan2
- TNPO1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV61523093; called by muse, varscan2
- TRPC4AP | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV52684790; called by muse, mutect2, varscan2
- TTC37 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV62457054; called by muse, mutect2, varscan2
- ZNF527 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV62235928; called by muse, mutect2, varscan2
- APOB | c.7740_7746dup p.Q2583Gfs*9 | Frame Shift Ins (INS) | VAF 50/137 reads (36%) | called by mutect2, varscan2
- CATIP | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CATIP | c.132_150del p.Q45Rfs*16 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, varscan2
- METTL2B | c.944dup p.R316Efs*3 | Frame Shift Ins (INS) | VAF 37/225 reads (16%) | called by mutect2, varscan2
- MYH11 | c.5622del p.G1875Afs*47 | Frame Shift Del (DEL) | VAF 29/68 reads (43%) | called by mutect2, varscan2
- TRMT1L | c.2066dup p.L689Ffs*22 | Frame Shift Ins (INS) | VAF 92/349 reads (26%) | called by mutect2, varscan2
- APCDD1 | c.603C>T p.A201= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs145453912, COSV62372937; called by muse, mutect2, varscan2
- CDK13 | c.2472T>C p.G824= | Silent (SNP) | VAF 66/142 reads (46%) | catalogued as COSV51701418; called by muse, mutect2, varscan2
- CDO1 | c.315A>G p.T105= | Silent (SNP) | VAF 113/286 reads (40%) | catalogued as rs1303630549, COSV51665871; called by muse, mutect2, varscan2
- COX4I2 | c.174C>T p.N58= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs539460095, COSV65782091; called by muse, mutect2, varscan2
- CTU2 | c.153C>T p.F51= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV56384009; called by muse, mutect2, varscan2
- CYP39A1 | c.441G>A p.L147= | Silent (SNP) | VAF 137/324 reads (42%) | catalogued as COSV51499523; called by muse, mutect2, varscan2
- EDNRA | c.816G>A p.A272= | Silent (SNP) | VAF 115/269 reads (43%) | catalogued as rs200693894, COSV60100549; called by muse, mutect2, varscan2
- FNDC3B | c.3193T>C p.L1065= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV61050379; called by muse, mutect2, varscan2
- IGHG3 | c.382C>A p.R128= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs370664311; called by muse, mutect2
- LCA5L | c.288A>G p.K96= | Silent (SNP) | VAF 119/292 reads (41%) | catalogued as COSV55747494; called by muse, mutect2, varscan2
- MUC6 | c.6588T>C p.P2196= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV70150730; called by muse, mutect2, varscan2
- NLRP12 | c.1452C>T p.H484= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs769866276, COSV60755872; called by muse, mutect2, varscan2
- NOS1 | c.465C>T p.P155= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs369224010; called by muse, mutect2, varscan2
- NRCAM | c.2160C>T p.R720= (on ENST00000379028 / NM_001371124.1; = p.R704= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1379623312, COSV61050032; called by muse, mutect2, varscan2
- PCDHA3 | c.1971C>G p.P657= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV63546471; called by muse, mutect2, varscan2
- PLXNA1 | c.2805C>A p.A935= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV52533022; called by muse, mutect2, varscan2
- PTPN22 | c.1731T>C p.Y577= (on ENST00000359785 / NM_001193431.2; = p.Y522= on NM_012411.5) | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as COSV63086807; called by muse, mutect2, varscan2
- RYR2 | c.4701G>T p.S1567= | Silent (SNP) | VAF 52/170 reads (31%) | catalogued as COSV63716488; called by muse, mutect2
